Surgical pathology report (de-identified scan), TCGA case TCGA-08-0350, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0350-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0350

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, right parietal lobe, biopsy: Glioblastoma multiforme, grade IV (WHO); see comment.
- B. Brain, right parietal lobe, resection: Glioblastoma multiforme, grade IV (WHO); see comment.
- C. Brain, right parietal lobe, biopsy: Glioblastoma multiforme, grade IV (WHO); see comment.

COMMENT: This glioblastoma multiforme is composed of extremely pleomorphic, bizarre cells, which are often multinucleated. The cytoplasm is primarily densely eosinophilic, consistent with a gemistocytic phenotype. A high percentage of the cells stain strongly for GFAP. Focally, the tumor can be seen infiltrating adjacent cortex. Mitoses, including abnormal mitotic figures, are easily identified. Microvascular proliferation is seen and focal necrosis is present. These features are diagnostic for glioblastoma multiforme by the [REDACTED] criteria. It is also a glioblastoma multiforme by the [REDACTED] criteria, and it is a grade 4 astrocytoma by the [REDACTED] criteria.

The results of MIB-1 staining will be reported by addendum.

Intraoperative Diagnosis

FS1 (A) Brain, right parietal lobe, biopsy: Glioblastoma multiforme, grade IV [REDACTED]. [REDACTED]

Gross Description

The specimen is received in three parts, labeled with the patient's name and medical record number.

Part A, received fresh and labeled "right parietal brain tumor," consists of a piece of tan, soft tissue measuring 0.8 x 0.3 x 0.2 cm in aggregate. A portion of the specimen is frozen for FS1 and is then

[page 2 of 2]
submitted in cassette A1. The remainder of the specimen is entirely submitted in cassette A2.

Part B, received in formalin and labeled "right parietal brain tumor," consists of multiple soft, pink-yellow-white, glistening, unoriented tissue fragments weighing 3.5 gm and measuring 4.5 x 1.7 x 1.7 cm in aggregate. The specimen is serially sectioned, revealing a pink-yellow, smooth cut surface. The specimen is entirely submitted in cassettes B1-B3.

Part C, received in formalin and labeled "right parietal brain tumor margin," consists of one soft, white-yellow, glistening, unoriented tissue fragment weighing < 0.1 gm and measuring 0.5 x 0.4 x 0.2 cm. The specimen is entirely submitted in cassette C1.

Clinical History

[REDACTED] with right parietal lobe lesion, with seizure activity (lesion is ring-enhancing; question of central necrosis).

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

ADDENDUM

Date of Addendum: [REDACTED]

Addendum Comment

The MIB-1 immunohistochemical labelling is 24.58%.

Source: NCI Genomic Data Commons file e37ee5bd-fd40-43c2-ba5f-f5a22f0204a5 (TCGA-08-0350.B38C8B69-82D0-4102-9544-571AB39E1B25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).